Gene-level copy-number profile of tumor specimen TCGA-63-7023-01A from TCGA case TCGA-63-7023, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA.
Specimen TCGA-63-7023-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.b1f5380f-a349-4ce3-8965-d302c41de726.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-63-7023-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/042b45e7-e645-481e-bb8a-d4b64bc5a8ac

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 23,375; copy number 2: 29,870; copy number 3: 3,682; copy number 4: 302; copy number 5: 1,977; copy number 6: 9; copy number 7: 455; copy number 8: 3; copy number 9: 59; copy number 12: 8; copy number 18: 12; copy number 19: 24; copy number 25: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-63-7023-01A-11D-1943-01): tumor purity 0.85, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–54,346, 2 genes: LINC01986, AC066595.1.
- chr3:58,607,080–58,666,834, 2 genes: FAM3D-AS1, FAM3D.
- chr4:81,919,995–82,013,095, 3 genes: COX5BP1, AC021863.1, NPM1P41.
- chr5:24,749,374–24,885,461, 6 genes: AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1.
- chr14:52,791,756–52,930,185, 1 gene (within-gene range 0–3): AL139317.5.
- chr14:52,857,268–53,023,597, 5 genes: FERMT2, AL139317.4, AL352979.4, AL352979.1, AL352979.3.
- chr14:53,036,755–53,038,251, 1 gene: AL352979.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,561 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:160,495,007–161,078,902, 8 genes, copy number 5 (within-gene range 4–5): KPNA4, SCARNA7, KRT8P12, RPL6P8, ARL14, SNORA72, AC069224.1, PPM1L.
- chr3:164,978,898–167,066,320, 21 genes, copy number 5–7: SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74.
- chr3:167,956,311–170,860,993, 54 genes, copy number 5 (within-gene range 4–5): AC128713.1, HMGN2P26, GOLIM4, AC069243.1, EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11, AC026316.4, MIR6828, SLC7A14-AS1, SLC7A14, KRT8P13.
- chr3:170,864,875–174,286,644, 43 genes, copy number 5 (within-gene range 2–5): RPL22L1, EIF5A2, AC061708.1, KLF7P1, RNU1-70P, SLC2A2, TNIK, MIR569, Y_RNA, AC092919.1, AC092919.2, RNU6-348P, AC008134.1, PLD1, TMEM212-AS1, TMEM212, TMEM212-IT1, AC055714.1, FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1, SPATA16, AC068759.1, NLGN1, AC092967.1, NLGN1-AS1, RN7SKP234.
- chr8:32,911,493–145,066,685, 1,759 genes, copy number 5 (broad region; genes not listed).
- chr9:114,666,434–115,402,644, 10 genes, copy number 5–6 (within-gene range 2–6): TEX48, AL160275.1, AL390240.1, TNFSF15, AL133412.1, DELEC1, TNFSF8, TNC, AL162425.1, AL355601.1.
- chr12:1,660,315–26,833,194, 655 genes, copy number 5–25 (broad region; genes not listed).
- chr14:48,045,481–48,228,216, 2 genes, copy number 8: AL359212.1, AL512358.1.
- chr14:53,948,427–54,471,218, 7 genes, copy number 5: MIR5580, BMP4, AL138479.2, ATP5F1CP1, CDKN3, CNIH1, AL359792.1.
- chr17:52,390,515–52,535,701, 1 gene, copy number 5: LINC01982.
- chr18:42,649,520–42,657,893, 1 gene, copy number 8: AC084335.1.

Autosomal genes at a single copy (total copy number 1): 20,989. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
